Somatic mutation profile of tumor specimen 159c49fd-40ff-4616-b6b6-be21a6 (aliquot 159c49fd-40ff-4616-b6b6-be21a6_D6) from CPTAC case 05CO002, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIA.
Specimen 159c49fd-40ff-4616-b6b6-be21a6: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a2e9dfc2-0d7d-4d6e-acef-7424df61af48.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen d271597e-f19c-4c55-b9dd-1a251a (Blood Derived Normal), aliquot d271597e-f19c-4c55-b9dd-1a251a_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6bc2d69d-669d-460a-bc5f-09c395ce26cd

The open-access MAF lists 137 somatic variants for this specimen: 97 protein-altering or splice-affecting, 31 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 80, Silent 31, Nonsense Mutation 9, Frame Shift Ins 3, 3'UTR 3, Frame Shift Del 2, RNA 2, Intron 2, 5'Flank 1, 3'Flank 1, In Frame Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.646C>T p.R216* | Nonsense Mutation (SNP) | VAF 33/57 reads (58%) | hotspot (GDC flag); catalogued as rs62619935, CM992133, COSV57320867; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GJA1 | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 37/253 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs750294638, CM030465, COSV56997002; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.832C>T p.P278S | Missense Mutation (SNP) | VAF 138/304 reads (45%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs17849781, CM011015, CM052927, CM120850, CX0910928, COSV52668132, COSV52679740, COSV52684662, COSV52950563; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACSM4 | c.472C>T p.R158* | Nonsense Mutation (SNP) | VAF 94/227 reads (41%) | catalogued as rs746836708, COSV101257265; called by muse, mutect2, varscan2
- ASXL1 | c.1972G>T p.G658* | Nonsense Mutation (SNP) | VAF 66/342 reads (19%) | catalogued as COSV60102589; called by muse, mutect2, varscan2
- ATP10A | c.2021C>T p.A674V | Missense Mutation (SNP) | VAF 39/184 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.244); catalogued as rs564272797, COSV63519452; called by muse, mutect2, varscan2
- BATF3 | c.371G>T p.C124F | Missense Mutation (SNP) | VAF 49/102 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); catalogued as COSV54659795; called by muse, mutect2, varscan2
- CD163L1 | c.2312G>A p.R771Q | Missense Mutation (SNP) | VAF 12/179 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs999063451, COSV58013113; called by muse, mutect2
- CSRP1 | c.362G>A p.R121Q | Missense Mutation (SNP) | VAF 100/167 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs757153693; called by muse, mutect2, varscan2
- DCAF8 | c.347G>A p.R116H | Missense Mutation (SNP) | VAF 63/285 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs376611740, COSV58785320; called by muse, mutect2, varscan2
- DNMT1 | c.4340C>T p.S1447L | Missense Mutation (SNP) | VAF 26/466 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as rs1387794444, COSV100532786; called by muse, mutect2
- DNTTIP2 | c.1848C>A p.N616K | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT tolerated (0.68); PolyPhen benign (0.007); catalogued as rs776400492; called by muse, mutect2, varscan2
- FBXL7 | c.824G>A p.R275H | Missense Mutation (SNP) | VAF 86/265 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as rs1286536913, COSV61642752; called by muse, mutect2, varscan2
- FER1L6 | c.3611A>G p.D1204G | Missense Mutation (SNP) | VAF 37/156 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV101206111; called by muse, mutect2, varscan2
- FLG2 | c.860G>A p.G287E | Missense Mutation (SNP) | VAF 40/315 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as COSV66173258; called by muse, mutect2, varscan2
- FNDC1 | c.955C>T p.R319C | Missense Mutation (SNP) | VAF 72/193 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779471491, COSV51940700; called by muse, mutect2, varscan2
- GABRA2 | c.280C>T p.R94* | Nonsense Mutation (SNP) | VAF 8/57 reads (14%) | catalogued as rs1428045491, COSV100734734, COSV62915909; called by muse, mutect2, varscan2
- GABRG2 | c.359C>T p.T120M | Missense Mutation (SNP) | VAF 54/186 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs1194128280, COSV62722068; called by muse, mutect2, varscan2
- GPR6 | c.868G>A p.A290T | Missense Mutation (SNP) | VAF 74/348 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.362); catalogued as rs1274651473, COSV51573848; called by muse, mutect2, varscan2
- H1-1 | c.307G>A p.G103R | Missense Mutation (SNP) | VAF 86/200 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201969543, COSV55120135; called by muse, mutect2, varscan2
- ITGAX | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs773816266; called by muse, mutect2, varscan2
- KCNA10 | c.200C>T p.P67L | Missense Mutation (SNP) | VAF 82/215 reads (38%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.028); catalogued as rs868838468, COSV63904631; called by muse, mutect2, varscan2
- KPNA5 | c.42G>T p.M14I | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as rs369865783; called by mutect2, varscan2
- LRP1 | c.9515G>A p.R3172H | Missense Mutation (SNP) | VAF 93/467 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); catalogued as COSV54508737; called by muse, mutect2, varscan2
- MAGEB6 | c.596C>T p.A199V | Missense Mutation (SNP) | VAF 33/226 reads (15%) | SIFT tolerated (0.97); PolyPhen benign (0.067); catalogued as rs1444873691, COSV66873476; called by muse, mutect2, varscan2
- MAGEC1 | c.106C>A p.Q36K | Missense Mutation (SNP) | VAF 68/244 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.042); catalogued as COSV53579687, COSV99596385; called by muse, mutect2, varscan2
- MAN2A2 | c.3068C>T p.A1023V | Missense Mutation (SNP) | VAF 27/140 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs373417566, COSV64638571; called by muse, mutect2, varscan2
- MICB | c.542G>A p.R181H | Missense Mutation (SNP) | VAF 31/192 reads (16%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as rs752885996; called by muse, mutect2, varscan2
- MTA3 | c.142C>T p.R48* | Nonsense Mutation (SNP) | VAF 22/54 reads (41%) | catalogued as rs1013525927; called by muse, mutect2, varscan2
- MUC12 | c.2954C>T p.T985M (on ENST00000379442; = p.T842M on NM_001164462.1) | Missense Mutation (SNP) | VAF 99/331 reads (30%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.788); catalogued as rs537437002; called by muse, mutect2, varscan2
- NAA11 | c.157G>A p.V53M | Missense Mutation (SNP) | VAF 59/238 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs748172819; called by muse, mutect2, varscan2
- NELL1 | c.1534G>A p.G512R | Missense Mutation (SNP) | VAF 47/139 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs768262280, COSV54241744, COSV54295117; called by muse, mutect2, varscan2
- NYAP2 | c.899C>T p.T300M | Missense Mutation (SNP) | VAF 31/139 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs376660568; called by muse, mutect2, varscan2
- PCDHB2 | c.250G>A p.G84R | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as COSV52035795; called by muse, mutect2, varscan2
- PCDHGA2 | c.592C>T p.R198C | Missense Mutation (SNP) | VAF 92/353 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.18); catalogued as COSV53955759; called by muse, mutect2, varscan2
- PCDHGA4 | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.034); catalogued as rs1561508033; called by muse, mutect2, varscan2
- PSKH2 | c.498G>T p.M166I | Missense Mutation (SNP) | VAF 84/264 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.472); catalogued as rs1211900544, COSV99404996; called by mutect2, varscan2
- PTPRC | c.989C>A p.T330N | Missense Mutation (SNP) | VAF 41/212 reads (19%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV61415724; called by mutect2, varscan2
- PTPRZ1 | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.925); catalogued as rs1385479485, COSV66443655; called by muse, mutect2, varscan2
- RECK | c.1838G>A p.R613H | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.076); catalogued as rs772507584, COSV65034653; called by muse, mutect2, varscan2
- RGS2 | c.190dup p.S64Kfs*12 | Frame Shift Ins (INS) | VAF 40/273 reads (15%) | catalogued as rs775439827; called by mutect2, varscan2
- RNF165 | c.229G>A p.A77T | Missense Mutation (SNP) | VAF 77/190 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV53974461; called by muse, mutect2, varscan2
- SIM1 | c.1319C>T p.S440L | Missense Mutation (SNP) | VAF 62/143 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.196); catalogued as rs776861600, COSV53497878, COSV99492589; called by muse, mutect2, varscan2
- SLC7A11 | c.1138C>T p.L380F | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1220740650; called by muse, mutect2, varscan2
- SOX6 | c.1651C>A p.P551T (on ENST00000528429 / NM_001145819.2; = p.P524T on NM_017508.3) | Missense Mutation (SNP) | VAF 60/162 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.119); catalogued as COSV57046594; called by mutect2, varscan2
- STARD8 | c.550G>A p.A184T | Missense Mutation (SNP) | VAF 29/234 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs757767955, COSV52926613; called by muse, mutect2, varscan2
- SULT1E1 | c.680C>T p.S227L | Missense Mutation (SNP) | VAF 42/121 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs201902818, COSV99895152; called by muse, mutect2, varscan2
- TAL1 | c.689G>A p.R230H | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754330586, COSV53745519; called by muse, mutect2, varscan2
- TEX47 | c.11C>T p.S4L | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as rs757553572, COSV51878714; called by muse, mutect2, varscan2
- TMPRSS15 | c.1217G>A p.R406Q | Missense Mutation (SNP) | VAF 46/130 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.403); catalogued as rs764089811, COSV53040591; called by muse, mutect2, varscan2
- TYK2 | c.2618-1G>T p.X873_splice | Splice Site (SNP) | VAF 68/213 reads (32%) | catalogued as COSV53388772; called by muse, mutect2, varscan2
- ULK3 | c.1123C>T p.R375C | Missense Mutation (SNP) | VAF 31/191 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as rs371226370; called by muse, mutect2, varscan2
- UPK1A | c.575G>A p.R192H | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.738); catalogued as rs1459561681; called by muse, mutect2, varscan2
- VCAN | c.187C>T p.R63C | Missense Mutation (SNP) | VAF 129/388 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs977327386, COSV54103469; called by muse, mutect2, varscan2
- VRTN | c.1546C>T p.R516C | Missense Mutation (SNP) | VAF 30/158 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs1013823696, COSV56441664, COSV56442010; called by muse, mutect2, varscan2
- ZNF860 | c.1336C>T p.R446* | Nonsense Mutation (SNP) | VAF 91/237 reads (38%) | catalogued as rs573670644; called by muse, mutect2, varscan2
- AMOTL2 | c.2009C>T p.S670F | Missense Mutation (SNP) | VAF 70/362 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ARID1A | c.2433del p.R811Sfs*22 | Frame Shift Del (DEL) | VAF 40/83 reads (48%) | called by mutect2, pindel, varscan2
- BCL9 | c.4012C>T p.Q1338* | Nonsense Mutation (SNP) | VAF 72/381 reads (19%) | called by muse, mutect2, varscan2
- C8orf48 | c.760C>T p.L254F | Missense Mutation (SNP) | VAF 53/132 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSPP1 | c.1888C>T p.P630S (on ENST00000676605; = p.P589S on NM_024790.6) | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- DRG1 | c.985C>G p.L329V | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); called by muse, mutect2, varscan2
- EHMT2 | c.3092T>C p.V1031A | Missense Mutation (SNP) | VAF 55/248 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- EVL | c.1213+7G>A | Splice Region (SNP) | VAF 40/92 reads (43%) | called by muse, mutect2, varscan2
- FGFR2 | c.748G>C p.E250Q | Missense Mutation (SNP) | VAF 88/269 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.465); called by muse, mutect2, varscan2
- FOXJ1 | c.1054C>T p.H352Y | Missense Mutation (SNP) | VAF 48/100 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- GJC1 | c.775C>T p.R259* | Nonsense Mutation (SNP) | VAF 85/190 reads (45%) | called by muse, mutect2, varscan2
- GJE1 | c.467A>G p.N156S | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GMPR | c.709G>T p.D237Y | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPR101 | c.1448G>T p.S483I | Missense Mutation (SNP) | VAF 15/198 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); called by muse, mutect2
- GPR173 | c.728C>A p.A243D | Missense Mutation (SNP) | VAF 144/396 reads (36%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KHDC4 | c.447dup p.A150Sfs*49 | Frame Shift Ins (INS) | VAF 4/38 reads (11%) | called by pindel, varscan2
- KIR3DL1 | c.605C>T p.T202I | Missense Mutation (SNP) | VAF 78/192 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.009); called by muse, mutect2
- LONP2 | c.691dup p.T231Nfs*8 | Frame Shift Ins (INS) | VAF 7/44 reads (16%) | called by mutect2, pindel, varscan2
- LRRN4 | c.1288G>T p.A430S | Missense Mutation (SNP) | VAF 61/228 reads (27%) | SIFT tolerated (0.5); PolyPhen benign (0.006); called by mutect2, varscan2
- MUC4 | c.2851_2852del p.Q951Nfs*13 | Frame Shift Del (DEL) | VAF 10/73 reads (14%) | called by pindel, varscan2
- NCKAP5 | c.5669C>A p.A1890D | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.59); called by muse, mutect2, varscan2
- NOS2 | c.298C>T p.L100F | Missense Mutation (SNP) | VAF 53/109 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR5K2 | c.557G>T p.R186I | Missense Mutation (SNP) | VAF 22/236 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); called by muse, mutect2
- PARP1 | c.1761G>T p.R587S | Missense Mutation (SNP) | VAF 55/198 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCDHGA10 | c.583T>C p.Y195H | Missense Mutation (SNP) | VAF 92/256 reads (36%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- PTPRQ | c.3767T>A p.L1256* (on ENST00000616559; = p.L1214* on NM_001145026.2) | Nonsense Mutation (SNP) | VAF 17/67 reads (25%) | called by muse, mutect2, varscan2
- RPL10 | c.262C>T p.R88W | Missense Mutation (SNP) | VAF 130/448 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- S1PR5 | c.1067T>G p.L356R | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- SAMD4A | c.1781G>A p.R594Q | Missense Mutation (SNP) | VAF 76/297 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- SOCS2 | c.257_262dup p.K87_T88insIK | In Frame Ins (INS) | VAF 32/208 reads (15%) | called by pindel, varscan2
- SYMPK | c.492G>T p.M164I | Missense Mutation (SNP) | VAF 46/134 reads (34%) | SIFT tolerated (0.52); PolyPhen benign (0.021); called by mutect2, varscan2
- SYNDIG1L | c.172G>T p.G58W | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- TCF7L2 | c.1129A>C p.S377R (on ENST00000355995 / NM_001367943.1; = p.S354R on NM_030756.5) | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TENM1 | c.2956C>A p.P986T | Missense Mutation (SNP) | VAF 134/386 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by mutect2, varscan2
- TET3 | c.3716G>A p.S1239N | Missense Mutation (SNP) | VAF 170/473 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.413); called by muse, mutect2, varscan2
- TNFRSF19 | c.600G>T p.K200N | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UGT2B11 | c.40C>A p.L14I | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- VWF | c.3872C>T p.A1291V | Missense Mutation (SNP) | VAF 82/452 reads (18%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.465); called by muse, mutect2, varscan2
- WDR75 | c.248A>C p.K83T | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); called by muse, mutect2
- ZNF257 | c.1282G>C p.E428Q | Missense Mutation (SNP) | VAF 54/178 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- ZNF841 | c.148C>A p.Q50K (on ENST00000426391 / NM_001369830.1; = p.Q166K on NM_001136499.1 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- AC098582.1 | c.1371G>A p.G457= | Silent (SNP) | VAF 8/45 reads (18%) | called by muse, mutect2, varscan2
- APEX2 | c.1383G>A p.A461= | Silent (SNP) | VAF 108/287 reads (38%) | catalogued as rs753073220, COSV100237847; called by muse, mutect2, varscan2
- ATP8A2 | c.135G>A p.T45= | Silent (SNP) | VAF 52/152 reads (34%) | catalogued as COSV54971735; called by muse, mutect2, varscan2
- B3GNT5 | c.882G>T p.G294= | Silent (SNP) | VAF 53/135 reads (39%) | catalogued as rs760987845; called by muse, mutect2, varscan2
- BMP2K | c.2676G>A p.Q892= | Silent (SNP) | VAF 80/169 reads (47%) | catalogued as rs1304541469; called by muse, mutect2, varscan2
- C8G | c.504G>A p.R168= | Silent (SNP) | VAF 61/181 reads (34%) | catalogued as COSV99812363; called by muse, mutect2, varscan2
- CACNA1A | c.831C>T p.P277= | Silent (SNP) | VAF 15/74 reads (20%) | catalogued as rs568635317, COSV64196245, COSV64210826; called by muse, mutect2, varscan2
- CCNP | c.759G>A p.A253= | Silent (SNP) | VAF 17/102 reads (17%) | called by muse, mutect2, varscan2
- CDC40 | c.1452A>G p.Q484= | Silent (SNP) | VAF 14/35 reads (40%) | called by muse, mutect2, varscan2
- CHAT | c.1173C>T p.D391= | Silent (SNP) | VAF 89/519 reads (17%) | catalogued as rs141690626; called by muse, mutect2, varscan2
- CREB1 | c.987A>G p.L329= (on ENST00000432329 / NM_134442.5; = p.L315= on NM_004379.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 11/30 reads (37%) | called by muse, mutect2, varscan2
- GTF3C1 | c.858C>T p.C286= | Silent (SNP) | VAF 8/93 reads (9%) | catalogued as rs372258230; called by mutect2, varscan2
- HYAL2 | c.954G>A p.A318= | Silent (SNP) | VAF 20/74 reads (27%) | catalogued as rs782364122; called by muse, varscan2
- IGLV4-3 | c.363C>T p.V121= | Silent (SNP) | VAF 55/245 reads (22%) | catalogued as rs763300944; called by muse, mutect2, varscan2
- IL6R | c.360C>T p.S120= | Silent (SNP) | VAF 15/83 reads (18%) | called by muse, mutect2, varscan2
- KCNA5 | c.279C>T p.P93= | Silent (SNP) | VAF 42/107 reads (39%) | catalogued as COSV52906394, COSV52908133; called by muse, mutect2, varscan2
- LMF1 | c.1251G>A p.A417= | Silent (SNP) | VAF 21/152 reads (14%) | catalogued as rs534939246, COSV99236230; called by muse, mutect2, varscan2
- MTAP | c.573G>A p.A191= | Silent (SNP) | VAF 48/144 reads (33%) | catalogued as rs372861176; called by muse, mutect2, varscan2
- MUC16 | c.14364C>T p.G4788= | Silent (SNP) | VAF 20/188 reads (11%) | called by muse, mutect2
- OR2F1 | c.144G>A p.L48= | Silent (SNP) | VAF 78/286 reads (27%) | catalogued as COSV67331199; called by muse, mutect2, varscan2
- PCDHGA3 | c.438G>A p.T146= | Silent (SNP) | VAF 16/140 reads (11%) | catalogued as COSV53909039; called by muse, mutect2, varscan2
- PIWIL3 | c.129G>A p.S43= | Silent (SNP) | VAF 16/70 reads (23%) | catalogued as rs144005682; called by muse, mutect2, varscan2
- PLAGL2 | c.459C>T p.S153= | Silent (SNP) | VAF 102/480 reads (21%) | catalogued as rs763119089, COSV55788590; called by muse, mutect2, varscan2
- PPL | c.3234G>A p.Q1078= | Silent (SNP) | VAF 15/296 reads (5%) | called by muse, mutect2
- PRSS1 | c.297C>T p.Y99= | Silent (SNP) | VAF 190/645 reads (29%) | catalogued as rs373659879, COSV61196178; called by muse, mutect2, varscan2
- PTCHD3 | c.726G>A p.A242= | Silent (SNP) | VAF 75/307 reads (24%) | catalogued as rs768736791, COSV71256499; called by muse, mutect2, varscan2
- ROR1 | c.108C>T p.V36= | Silent (SNP) | VAF 38/86 reads (44%) | called by muse, mutect2, varscan2
- SLCO1A2 | c.1815G>A p.P605= | Silent (SNP) | VAF 18/84 reads (21%) | catalogued as rs772790612, COSV56602631; called by muse, mutect2, varscan2
- SYNE3 | c.1014G>A p.K338= | Silent (SNP) | VAF 67/218 reads (31%) | called by muse, mutect2, varscan2
- ZNF197 | c.141A>G p.Q47= | Silent (SNP) | VAF 28/77 reads (36%) | catalogued as rs542227356; called by muse, mutect2, varscan2
- ZNF675 | c.1353C>T p.P451= | Silent (SNP) | VAF 34/161 reads (21%) | catalogued as rs929679779; called by muse, mutect2, varscan2
- AC136759.1 | n.1329T>A | RNA (SNP) | VAF 7/27 reads (26%) | catalogued as rs1369887232; called by muse, mutect2, varscan2
- C7orf50 | c.*18G>A | 3'UTR (SNP) | VAF 23/73 reads (32%) | catalogued as rs750293122; called by muse, mutect2, varscan2
- CCDC88C | c.4442-2189C>T | Intron (SNP) | VAF 8/40 reads (20%) | catalogued as rs922437748; called by muse, mutect2, varscan2
- ITIH5 | c.940-14491C>T | Intron (SNP) | VAF 28/98 reads (29%) | catalogued as rs756281641; called by muse, mutect2, varscan2
- MIR124-2 | chr8:64377517 C>A | 5'Flank (SNP) | VAF 49/142 reads (35%) | called by muse, varscan2
- MMAB | c.*1468G>A | 3'UTR (SNP) | VAF 31/87 reads (36%) | catalogued as rs1228894697; called by muse, mutect2, varscan2
- OR2U1P | n.739C>A | RNA (SNP) | VAF 64/305 reads (21%) | called by muse, mutect2, varscan2
- SLC11A2 | chr12:50981663 G>T | 3'Flank (SNP) | VAF 22/54 reads (41%) | catalogued as rs536583175; called by muse, mutect2, varscan2
- TCTN1 | c.*59G>A | 3'UTR (SNP) | VAF 33/90 reads (37%) | catalogued as rs945272130; called by muse, mutect2, varscan2
